MMRF case MMRF_2566 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ed886847-8c83-47dc-81c9-435e079a30d0

Demographics
Sex at birth: male; Race: white; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.2 years (20,910 days); ISS stage: I; Days to last known disease status: 541 days (1.5 years); Days to last follow up: 541 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 74 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 241 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 330 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.37 mg/dL.
- Day 73 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 3.12 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.24 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 5.48 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.99 mmol/L.
- Day 253 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 3.26 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 4.57 mmol/L.
- Day 338 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 5.66 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.72 µg/mL; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 453 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 8.4 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 541 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 5.05 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -11: Weight: 93 kg; Height: 183 cm.

Biospecimens (2 samples)
- Sample MMRF_2566_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2566_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
